Somatic mutation profile of tumor specimen 0DGJ79 from CCDI case PBBTEJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infantile fibrosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 0.3 years (93 days).
Specimen 0DGJ79: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 368a25a3-c71b-4486-a9bc-5fdb5f1df4fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGJ60 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c170969c-667b-4cd8-a26e-fcea0c18bd0b

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GFPT1 | c.1898G>A p.R633Q (on ENST00000357308 / NM_001244710.2; = p.R615Q on NM_002056.4) | Missense Mutation (SNP) | VAF 232/730 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV61947419; called by muse, mutect2, varscan2
- IFNA7 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 372/1090 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCND3 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 44/574 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- PLA2G12B | c.264C>T p.C88= | Silent (SNP) | VAF 80/1416 reads (6%) | catalogued as rs779281191, COSV65978143; called by muse, mutect2
